Somatic mutation profile of tumor specimen TCGA-AN-A046-01A (aliquot TCGA-AN-A046-01A-21W-A050-09) from TCGA case TCGA-AN-A046, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.9 years (25,158 days).
Specimen TCGA-AN-A046-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a878d6a8-d527-4626-9af5-e783f6ce4482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A046-10A (Blood Derived Normal), aliquot TCGA-AN-A046-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/205f7120-573f-4dc4-94e2-1fb25302ff30

The open-access MAF lists 5,978 somatic variants for this specimen: 4,813 protein-altering or splice-affecting, 1,059 silent, 106 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,000, Silent 1,059, Nonsense Mutation 691, Splice Site 70, Intron 53, Splice Region 31, RNA 31, Frame Shift Ins 13, 5'UTR 7, Nonstop Mutation 6, 3'UTR 6, 5'Flank 6.

Variants (750 of 5,978; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as rs886043986, COSV55597437; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2869C>T p.R957* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as rs121918440, CM981521, COSV55934187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 20/193 reads (10%) | catalogued as rs1414406816, COSV57338187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 64/269 reads (24%) | hotspot (GDC flag); catalogued as COSV55455231; called by muse, mutect2, varscan2
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- DEPDC5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 39/317 reads (12%) | catalogued as rs772872014, CM146220, COSV56694430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- DNAH8 | c.10951C>T p.R3651* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as rs769929539, COSV59438495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDA | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 110/702 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs132630312, CM980583, COSV65772037; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | catalogued as rs376526037; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.5143C>T p.R1715* | Nonsense Mutation (SNP) | VAF 43/308 reads (14%) | catalogued as rs137852439, CM900094, CM920258, COSV64271015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFM2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs761283105, COSV57191541; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- GNE | c.922C>T p.R308C (on ENST00000396594 / NM_001128227.3; = p.R277C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs762106720, CM086833, CM139083, COSV64951631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.2563C>T p.R855* (on ENST00000642864 / NM_001111125.3; = p.R650* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as rs587777261, CM129316, COSV64724818; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 93/320 reads (29%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 36/195 reads (18%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MSH6 | c.2764C>T p.R922* | Nonsense Mutation (SNP) | VAF 57/193 reads (30%) | catalogued as rs587779246, CM117497, COSV52274217; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 39/243 reads (16%) | catalogued as rs587783786, COSV60334594; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFIA | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886039429, COSV64535682; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as rs1485445500, COSV58629409; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 41/122 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 56/165 reads (34%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 90/308 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RTKN2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 26/152 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs778526220, COSV65680028; called by muse, mutect2, varscan2
- SACS | c.10939G>T p.E3647* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as rs1156566314, COSV66538422, COSV66541147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SASH1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs587781245, CM155722, COSV66560894; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC19A2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as rs74315373, CM991264, COSV52546848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 90/434 reads (21%) | catalogued as rs367958902, CM020795; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 19/183 reads (10%) | catalogued as rs753621591, CM121226, COSV56252267; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC22D2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 20/153 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62622374, COSV62622441; called by muse, mutect2, varscan2
- UPF3B | c.1288C>T p.R430* (on ENST00000276201 / NM_080632.3; = p.R417* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 67/553 reads (12%) | catalogued as rs122468181, CM074621, COSV52229788; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WDR35 | c.1415G>A p.R472Q (on ENST00000345530 / NM_001006657.2; = p.R461Q on NM_020779.4) | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs200140363, COSV55601925, COSV99852911; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 60/218 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- A2ML1 | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV55289148; called by muse, mutect2, varscan2
- AADAC | c.880G>T p.G294* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV51758243, COSV51758945; called by muse, mutect2, varscan2
- AAK1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1267207277, COSV68643199; called by muse, mutect2, varscan2
- ABCA1 | c.4559G>T p.S1520I | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV66065422; called by muse, mutect2, varscan2
- ABCA1 | c.380A>C p.K127T | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV66058337; called by muse, mutect2, varscan2
- ABCA10 | c.1433A>C p.N478T | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52220668; called by muse, mutect2, varscan2
- ABCA12 | c.6605C>T p.S2202F (on ENST00000272895 / NM_173076.3; = p.S1884F on NM_015657.3) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55955370; called by muse, mutect2, varscan2
- ABCA13 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101329972, COSV70026557; called by muse, mutect2
- ABCA13 | c.11251A>G p.T3751A | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV101446860, COSV71286088; called by muse, mutect2, varscan2
- ABCA5 | c.4316G>A p.R1439Q | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369202022; called by muse, mutect2
- ABCA5 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV67016403; called by muse, mutect2, varscan2
- ABCA6 | c.3739G>T p.E1247* | Nonsense Mutation (SNP) | VAF 139/1006 reads (14%) | catalogued as COSV52637579; called by muse, mutect2, varscan2
- ABCA6 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs138416476, COSV52637314; called by muse, mutect2
- ABCA6 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 73/253 reads (29%) | catalogued as COSV52637588; called by muse, mutect2, varscan2
- ABCA7 | c.5261G>A p.R1754Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs761741121, COSV54027729, COSV54035314, COSV54037489; called by muse, mutect2, varscan2
- ABCA9 | c.4301G>T p.S1434I | Missense Mutation (SNP) | VAF 54/481 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60623104, COSV60623379; called by muse, mutect2, varscan2
- ABCA9 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60623390; called by muse, mutect2, varscan2
- ABCB11 | c.1674G>T p.Q558H | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as CM099347, COSV55588773; called by muse, mutect2, varscan2
- ABCB11 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 22/165 reads (13%) | catalogued as COSV55588791; called by muse, mutect2, varscan2
- ABCB5 | c.1609C>T p.R537C (on ENST00000404938 / NM_001163941.2; = p.R92C on NM_178559.6) | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs147534424; called by muse, mutect2, varscan2
- ABCB5 | c.3136G>T p.V1046L (on ENST00000404938 / NM_001163941.2; = p.V601L on NM_178559.6) | Missense Mutation (SNP) | VAF 91/643 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as COSV51707703; called by muse, mutect2, varscan2
- ABCB6 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772815355, COSV54693434; called by muse, mutect2, varscan2
- ABCC10 | c.1864G>A p.E622K (on ENST00000372530 / NM_001198934.2; = p.E594K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs762168388, COSV55086592; called by mutect2, varscan2
- ABCC10 | c.3004C>T p.R1002C (on ENST00000372530 / NM_001198934.2; = p.R974C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs201353470; called by muse, mutect2
- ABCC2 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs748245551, COSV64970648, COSV64970740; called by muse, mutect2, varscan2
- ABCC2 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs754646220, COSV64985593; called by muse, mutect2, varscan2
- ABCC3 | c.2877C>A p.F959L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53320006; called by muse, mutect2, varscan2
- ABCC4 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs968582757, COSV65311644, COSV65318605; called by muse, mutect2, varscan2
- ABCC8 | c.4410C>T p.L1470= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as rs369810811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG5 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs148131742, COSV53211226; called by muse, mutect2, varscan2
- ABCG8 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs773824087, COSV55392314; called by muse, mutect2, varscan2
- ABHD18 | c.1150C>T p.R384* (on ENST00000398965 / NM_001039717.2; = p.R291* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 56/192 reads (29%) | catalogued as rs1355205312, COSV66293606; called by muse, mutect2, varscan2
- ABHD3 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV56675686; called by muse, mutect2, varscan2
- ABI1 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs772279539, COSV61016357; called by muse, mutect2, varscan2
- ABI2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53691053; called by muse, mutect2, varscan2
- ABLIM3 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58642140; called by muse, mutect2, varscan2
- ABO | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV71743500; called by muse, mutect2, varscan2
- ABRAXAS1 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV58948592; called by muse, mutect2, varscan2
- ABTB2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.976); catalogued as COSV54386824; called by muse, mutect2, varscan2
- AC006059.2 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 143/1078 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV59606530; called by muse, mutect2, varscan2
- AC013489.1 | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51550922; called by muse, mutect2, varscan2
- AC136428.1 | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs758850253, COSV101434956; called by muse, mutect2, varscan2
- ACAD10 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 57/451 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766583324, COSV58155640; called by muse, mutect2, varscan2
- ACADL | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.493); catalogued as COSV52053021; called by muse, mutect2, varscan2
- ACBD6 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 67/502 reads (13%) | catalogued as COSV62573072; called by muse, mutect2, varscan2
- ACCSL | c.1049+1G>A p.X350_splice | Splice Site (SNP) | VAF 19/147 reads (13%) | catalogued as COSV66580928; called by muse, mutect2, varscan2
- ACO2 | c.2250G>T p.E750D | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV53442385; called by muse, varscan2
- ACO2 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs201102346; called by muse, varscan2
- ACOX3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs762558027, COSV62711619; called by muse, mutect2, varscan2
- ACOXL | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 108/502 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV67735225; called by muse, mutect2, varscan2
- ACP3 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV60485471; called by muse, mutect2
- ACRBP | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs367723803, COSV57523582; called by muse, mutect2, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by muse, mutect2, varscan2
- ACSBG2 | c.1598T>C p.V533A | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV53124035; called by muse, mutect2, varscan2
- ACSBG2 | c.1689G>A p.M563I | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53124045; called by muse, mutect2, varscan2
- ACSL1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1346627652, COSV55661967; called by muse, mutect2, varscan2
- ACSL1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs202112997, COSV55660942; called by muse, mutect2, varscan2
- ACSL1 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 76/238 reads (32%) | catalogued as rs1361601006, COSV55660967; called by muse, varscan2
- ACSL4 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV61614003; called by muse, mutect2, varscan2
- ACSL6 | c.691G>A p.E231K (on ENST00000379240; = p.E256K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV57297051; called by muse, mutect2, varscan2
- ACSM2A | c.991C>A p.L331I (on ENST00000219054; = p.L252I on NM_001308169.2) | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54582392; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACSM4 | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as COSV68067513; called by muse, varscan2
- ACSS3 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747927464, COSV54083690, COSV54089075; called by muse, mutect2, varscan2
- ACTG2 | c.367-1G>T p.X123_splice | Splice Site (SNP) | VAF 23/220 reads (10%) | catalogued as COSV61828107; called by muse, mutect2, varscan2
- ACTL6A | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as COSV101199648; called by muse, mutect2
- ACTN3 | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.386); catalogued as COSV100074287, COSV59748275; called by muse, mutect2, varscan2
- ACTR10 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 41/155 reads (26%) | catalogued as rs1397422376, COSV54297993; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | catalogued as COSV53200814, COSV53203777; called by muse, mutect2, varscan2
- ACTR2 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV53200425; called by muse, mutect2, varscan2
- ACTR2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs746974315, COSV53200450; called by muse, mutect2, varscan2
- ACTR3 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | catalogued as COSV54300444; called by muse, mutect2, varscan2
- ACTR5 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs765426755, COSV54759930, COSV54760969; called by muse, mutect2, varscan2
- ACTR8 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as COSV51635989; called by muse, mutect2, varscan2
- ADAD1 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56641122, COSV56642830; called by muse, mutect2, varscan2
- ADAM18 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 29/115 reads (25%) | catalogued as COSV55843485, COSV55846117; called by muse, mutect2, varscan2
- ADAM19 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 22/146 reads (15%) | catalogued as COSV57427667; called by muse, mutect2, varscan2
- ADAM7 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 60/606 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs200101638, COSV51548017; called by muse, mutect2, varscan2
- ADAMTS12 | c.4668G>T p.K1556N | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV61260583; called by muse, mutect2, varscan2
- ADAMTS12 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371132100, COSV61261873; called by muse, mutect2
- ADAMTS19 | c.2342G>T p.R781I | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50741863; called by muse, mutect2, varscan2
- ADAMTS20 | c.5239T>C p.Y1747H | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV67130031; called by muse, mutect2
- ADAMTS20 | c.3506G>T p.G1169V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67130033, COSV67139980; called by muse, mutect2, varscan2
- ADAMTS20 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs373577605, COSV67130038; called by muse, mutect2, varscan2
- ADAMTS3 | c.3131A>G p.K1044R | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs754727209, COSV54389319; called by muse, mutect2, varscan2
- ADAMTS3 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54389326, COSV54396001; called by muse, mutect2, varscan2
- ADAMTS5 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs753190231, COSV53178906; called by mutect2, varscan2
- ADAMTS5 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | catalogued as rs777065435, COSV53177958; called by muse, mutect2, varscan2
- ADAMTS5 | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.706); catalogued as COSV53175734; called by muse, mutect2, varscan2
- ADAMTS6 | c.1748G>T p.R583I | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66858801; called by muse, mutect2, varscan2
- ADAMTSL3 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV54444028; called by muse, mutect2, varscan2
- ADAR | c.3477G>T p.K1159N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1268794909, COSV52714157; called by muse, mutect2, varscan2
- ADCY1 | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52032703; called by muse, mutect2, varscan2
- ADCY9 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs772697228, COSV53574136; called by muse, mutect2, varscan2
- ADD2 | c.782T>G p.F261C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV52458951; called by muse, varscan2
- ADD2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781842295, COSV52458987; called by muse, varscan2
- ADGRB3 | c.1823G>T p.R608I | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs747988050, COSV101000147, COSV65382174; called by muse, varscan2
- ADGRB3 | c.1871G>T p.R624I | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65391216, COSV65405921; called by muse, varscan2
- ADGRB3 | c.2714A>G p.Y905C | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53240908; called by muse, mutect2, varscan2
- ADGRE1 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV51674553, COSV99165187; called by muse, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by muse, mutect2
- ADGRF2 | c.926C>A p.S309Y (on ENST00000296862 / NM_001368115.2; = p.S241Y on NM_153839.7) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57287789, COSV57288447; called by muse, mutect2, varscan2
- ADGRF5 | c.3129G>T p.K1043N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.52); catalogued as rs1376923140, COSV51932505, COSV51935195; called by muse, mutect2, varscan2
- ADGRG2 | c.2550C>A p.F850L (on ENST00000379869 / NM_001079858.3; = p.F847L on NM_005756.4) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV61338544; called by muse, mutect2, varscan2
- ADGRG2 | c.1965G>T p.K655N (on ENST00000379869 / NM_001079858.3; = p.K652N on NM_005756.4) | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61338549; called by muse, mutect2, varscan2
- ADGRG4 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 214/751 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.054); catalogued as COSV54953822; called by muse, mutect2, varscan2
- ADGRG4 | c.2399C>A p.S800Y | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99794867; called by muse, mutect2
- ADGRG4 | c.6127C>A p.L2043M | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV54953832; called by muse, mutect2, varscan2
- ADGRG4 | c.8472T>G p.F2824L | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV54953846; called by muse, mutect2, varscan2
- ADGRG7 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV56295442, COSV56296535; called by muse, mutect2, varscan2
- ADGRL2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54662946, COSV54684897, COSV54688211; called by muse, mutect2, varscan2
- ADGRL2 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV54662979; called by muse, mutect2, varscan2
- ADGRL4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV66058992; called by muse, mutect2, varscan2
- ADGRV1 | c.8752G>T p.E2918* | Nonsense Mutation (SNP) | VAF 38/318 reads (12%) | catalogued as COSV67983242; called by muse, mutect2, varscan2
- ADGRV1 | c.17063G>A p.R5688Q | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs374682222; called by muse, mutect2, varscan2
- ADGRV1 | c.17315G>A p.R5772Q | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779918762, COSV101315662; called by muse, mutect2
- ADHFE1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52554528; called by muse, mutect2, varscan2
- ADNP | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62425017; called by muse, mutect2, varscan2
- ADNP | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV62425023; called by muse, mutect2, varscan2
- ADPGK | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as rs752942617, COSV61173705; called by mutect2, varscan2
- ADRB2 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100019125; called by muse, mutect2, varscan2
- ADSS2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs749735276, COSV63694895; called by muse, mutect2, varscan2
- AEBP2 | c.676A>G p.S226G | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs1317693912, COSV56862964; called by muse, varscan2
- AEBP2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56862972; called by muse, mutect2, varscan2
- AFAP1L2 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | catalogued as COSV100413149, COSV58413917; called by muse, mutect2, varscan2
- AFF2 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 49/393 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60661549; called by muse, mutect2, varscan2
- AFF2 | c.3556A>G p.M1186V | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV53985175; called by muse, mutect2, varscan2
- AFF4 | c.2552C>T p.T851M | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as rs769422062, COSV54793685; called by muse, mutect2, varscan2
- AGBL1 | c.3052C>T p.L1018F | Missense Mutation (SNP) | VAF 78/309 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1171738725, COSV66855086; called by muse, mutect2, varscan2
- AGBL5 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983091121, COSV59936287, COSV59936860; called by muse, mutect2, varscan2
- AGBL5 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV59936295; called by muse, mutect2, varscan2
- AGK | c.711T>G p.F237L | Missense Mutation (SNP) | VAF 115/465 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV62594254; called by muse, mutect2, varscan2
- AGL | c.1243A>C p.K415Q | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV54051395; called by muse, mutect2, varscan2
- AGMAT | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768542408, COSV65435781; called by muse, mutect2, varscan2
- AGMO | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61109625; called by muse, varscan2
- AGO3 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1466158162, COSV55791614; called by muse, mutect2, varscan2
- AGO4 | c.2068C>T p.R690* | Nonsense Mutation (SNP) | VAF 47/173 reads (27%) | catalogued as rs200474840, COSV64616888; called by muse, mutect2, varscan2
- AGTPBP1 | c.2620C>T p.R874W (on ENST00000357081 / NM_001330701.2; = p.R834W on NM_015239.2) | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1418982979, COSV61270623; called by muse, mutect2, varscan2
- AGTR1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762020328, CM1514785, COSV62557225, COSV62558442; called by muse, mutect2, varscan2
- AGTR1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200184769, COSV62557211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTR2 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV64156370; called by muse, mutect2, varscan2
- AGXT2 | c.1501T>G p.F501V | Missense Mutation (SNP) | VAF 138/947 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV51485511; called by muse, mutect2, varscan2
- AHCTF1 | c.554G>A p.R185Q (on ENST00000366508; = p.R159Q on NM_015446.5) | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58248664; called by muse, mutect2, varscan2
- AHNAK | c.16294G>A p.E5432K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as rs1430442461, COSV57210516; called by muse, mutect2, varscan2
- AHNAK | c.15243G>T p.K5081N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57210530; called by muse, mutect2, varscan2
- AHNAK | c.13951A>C p.K4651Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV99946361; called by muse, mutect2
- AHNAK | c.5998G>T p.G2000C | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57210543; called by muse, mutect2, varscan2
- AHNAK | c.4704G>T p.K1568N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57210559; called by muse, mutect2, varscan2
- AIMP2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.307); catalogued as COSV56150428; called by muse, mutect2, varscan2
- AK5 | c.1414G>T p.E472* (on ENST00000354567 / NM_174858.3; = p.E446* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | catalogued as COSV60968300, COSV60971368; called by muse, mutect2, varscan2
- AK6 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 28/239 reads (12%) | catalogued as COSV51457270; called by muse, mutect2, varscan2
- AK7 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV99967086; called by muse, mutect2, varscan2
- AK7 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 64/580 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs114393353, COSV50870705, COSV50881490; called by muse, mutect2, varscan2
- AKAP11 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 60/166 reads (36%) | catalogued as rs1167550085, COSV50295210; called by muse, mutect2, varscan2
- AKAP13 | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs747774362, COSV63453850; called by muse, mutect2, varscan2
- AKAP13 | c.3318G>T p.E1106D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1228531599, COSV63470860; called by muse, mutect2, varscan2
- AKAP3 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs773529110, COSV57415683; called by mutect2, varscan2
- AKAP4 | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62074182; called by muse, mutect2, varscan2
- AKAP6 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868161302, COSV55209617; called by muse, mutect2, varscan2
- AKAP6 | c.4955G>A p.R1652Q | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763532229, COSV55208487; called by muse, mutect2, varscan2
- AKAP9 | c.1370T>C p.M457T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV62343498; called by muse, mutect2, varscan2
- AKAP9 | c.1739A>C p.E580A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV62343510; called by muse, mutect2, varscan2
- AKAP9 | c.2241A>C p.E747D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV62343522; called by muse, mutect2, varscan2
- AKAP9 | c.4222A>T p.K1408* | Nonsense Mutation (SNP) | VAF 24/205 reads (12%) | catalogued as COSV62343538; called by muse, mutect2, varscan2
- AKAP9 | c.5602G>T p.D1868Y (on ENST00000359028; = p.D1836Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62343552; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/150 reads (24%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKAP9 | c.11419C>T p.R3807* (on ENST00000359028; = p.R3783* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/178 reads (30%) | catalogued as rs376277241; called by muse, mutect2, varscan2
- AKNAD1 | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 48/267 reads (18%) | catalogued as COSV64172037; called by muse, mutect2, varscan2
- AKR1C4 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV54122982, COSV99578579; called by muse, mutect2, varscan2
- AL121758.1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | PolyPhen benign (0.412); catalogued as rs375211313; called by muse, mutect2, varscan2
- AL136295.1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs575738905, COSV99841673; called by muse, mutect2
- ALCAM | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 71/276 reads (26%) | catalogued as COSV100064559, COSV60247134; called by muse, mutect2, varscan2
- ALDH1A1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs927636872, COSV52790587; called by muse, mutect2, varscan2
- ALDH6A1 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV63246210; called by muse, mutect2, varscan2
- ALG13 | c.3271G>T p.D1091Y | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV52637789; called by muse, mutect2, varscan2
- ALG9 | c.1229C>T p.S410L (on ENST00000614444 / NM_001352418.1; = p.S417L on NM_024740.2) | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1481046325, COSV67644137; called by muse, mutect2, varscan2
- ALK | c.3362G>A p.G1121D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs55760835; ClinVar: uncertain significance; called by muse, mutect2
- ALKBH8 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV52834619; called by muse, mutect2, varscan2
- ALLC | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV52993925, COSV52995824, COSV52997223; called by muse, mutect2, varscan2
- ALMS1 | c.1133A>C p.E378A | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV52507624; called by muse, mutect2, varscan2
- ALMS1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs769734500, COSV52507633; called by muse, mutect2, varscan2
- ALMS1 | c.3162G>T p.E1054D | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV52507641; called by muse, mutect2, varscan2
- ALPK2 | c.5051C>A p.S1684Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV100864211; called by muse, mutect2
- ALPK2 | c.3986C>A p.S1329Y | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV64492106; called by muse, mutect2
- ALPL | c.1186T>C p.F396L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.789); catalogued as COSV66376124; called by muse, mutect2, varscan2
- AMER2 | c.1912A>C p.K638Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63437065; called by muse, mutect2, varscan2
- AMER3 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV58466116, COSV58466188; called by muse, varscan2
- AMER3 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV58466125; called by muse, varscan2
- AMIGO1 | c.1083C>A p.F361L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV63990343; called by muse, mutect2, varscan2
- AMPD1 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1354451905, COSV62415508; called by muse, mutect2, varscan2
- ANAPC1 | c.5782T>G p.L1928V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV61975470; called by mutect2, varscan2
- ANAPC4 | c.1328A>C p.K443T | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100193899; called by muse, varscan2
- ANGPTL3 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs766843384, COSV52002342; called by muse, mutect2, varscan2
- ANGPTL5 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57532630; called by muse, varscan2
- ANGPTL5 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV100527710, COSV57534628; called by muse, mutect2
- ANK2 | c.7594G>T p.G2532W | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52156166; called by mutect2, varscan2
- ANK2 | c.8177C>A p.T2726N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV52156180; called by muse, mutect2, varscan2
- ANK2 | c.11587G>A p.D3863N | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.299); catalogued as rs886039041, COSV52156189; ClinVar: uncertain significance; called by muse, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANK3 | c.3794C>A p.P1265H (on ENST00000280772 / NM_001320874.2; = p.P399H on NM_001149.3) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55053170; called by muse, mutect2, varscan2
- ANK3 | c.2756C>T p.S919L (on ENST00000280772 / NM_001320874.2; = p.S53L on NM_001149.3) | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775705277, COSV55053192; called by muse, mutect2, varscan2
- ANKEF1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139485632; called by mutect2, varscan2
- ANKFY1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs745379002, COSV58916616; called by muse, mutect2, varscan2
- ANKH | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs142872069; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2843C>A p.S948Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as rs755308583, COSV51844925; called by muse, mutect2, varscan2
- ANKRD10 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779123844, COSV57442692; called by muse, mutect2, varscan2
- ANKRD10 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 32/209 reads (15%) | catalogued as COSV57443365; called by muse, mutect2, varscan2
- ANKRD12 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 31/176 reads (18%) | catalogued as COSV50822578; called by muse, mutect2, varscan2
- ANKRD12 | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.343); catalogued as COSV50822623; called by muse, mutect2, varscan2
- ANKRD17 | c.5234G>A p.G1745D | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429273, COSV58218660; called by muse, mutect2, varscan2
- ANKRD24 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758310661, COSV53668981; called by muse, mutect2, varscan2
- ANKRD26 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 20/141 reads (14%) | catalogued as COSV65774940, COSV65775491; called by muse, mutect2, varscan2
- ANKRD26 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 65/415 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV65793830; called by muse, mutect2, varscan2
- ANKRD27 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV60130764; called by muse, mutect2, varscan2
- ANKRD27 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs766519033, COSV60128664; called by muse, mutect2, varscan2
- ANKRD28 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV67517656; called by muse, varscan2
- ANKRD30A | c.1366G>T p.E456* (on ENST00000611781; = p.E400* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV64608363; called by muse, mutect2, varscan2
- ANKRD34B | c.1085G>T p.R362I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV58613483; called by muse, mutect2, varscan2
- ANKRD34B | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775271852, COSV58613748; called by muse, mutect2, varscan2
- ANKRD55 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV61944174; called by muse, mutect2, varscan2
- ANKS6 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs1306952839, COSV62049044; called by muse, mutect2, varscan2
- ANO10 | c.333T>G p.F111L | Missense Mutation (SNP) | VAF 78/524 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV52730150; called by muse, mutect2, varscan2
- ANO4 | c.2131G>T p.D711Y (on ENST00000392977 / NM_001286615.2; = p.D676Y on NM_178826.4) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as COSV54588684, COSV54592568; called by muse, mutect2, varscan2
- ANO4 | c.2338C>A p.L780I (on ENST00000392977 / NM_001286615.2; = p.L745I on NM_178826.4) | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV54592579, COSV54594505; called by muse, mutect2, varscan2
- ANO5 | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61083995, COSV61087405; called by muse, varscan2
- ANP32A | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 21/206 reads (10%) | catalogued as COSV51189496; called by muse, mutect2, varscan2
- ANP32B | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100233206; called by muse, mutect2
- ANXA1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57411031; called by muse, varscan2
- ANXA10 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 23/215 reads (11%) | catalogued as rs374810057; called by muse, mutect2, varscan2
- ANXA4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1048992360, COSV67848677; called by muse, mutect2, varscan2
- ANXA6 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs748009214, COSV62905611; called by muse, mutect2, varscan2
- AOC2 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53198784; called by mutect2, varscan2
- AOC2 | c.2201C>A p.P734H (on ENST00000253799 / NM_009590.4; = p.P707H on NM_001158.5) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53825779; called by muse, mutect2
- AOC3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs146487990, COSV53824623; called by muse, mutect2, varscan2
- AOPEP | c.*2G>A | Splice Region (SNP) | VAF 44/251 reads (18%) | catalogued as rs1371457553, COSV52988837; called by muse, mutect2, varscan2
- AOX1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 42/287 reads (15%) | catalogued as rs754596150, COSV65981094; called by muse, mutect2, varscan2
- AP2B1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51998618; called by muse, mutect2, varscan2
- AP3B1 | c.1093A>C p.K365Q | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV54881678; called by muse, varscan2
- AP3M1 | c.806T>G p.L269R | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); catalogued as rs535082272, COSV62331104; called by muse, mutect2, varscan2
- APAF1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54489317; called by muse, mutect2, varscan2
- APAF1 | c.2057C>A p.S686Y (on ENST00000551964 / NM_181861.2; = p.S675Y on NM_001160.3) | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as COSV59663360; called by muse, mutect2, varscan2
- APAF1 | c.2200G>T p.E734* (on ENST00000551964 / NM_181861.2; = p.E723* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 77/279 reads (28%) | catalogued as COSV59663368; called by muse, mutect2, varscan2
- APBA1 | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV55225916; called by muse, mutect2, varscan2
- APBB1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1367774259, COSV100193758; called by muse, mutect2
- APC | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as CD020833, COSV57338198, COSV57350164; called by muse, mutect2, varscan2
- APC | c.4097C>T p.A1366V | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1561589807, COSV57334046, COSV57364839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267600319, CM995167, COSV57324455, COSV57326621, COSV57333132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5415C>A p.F1805L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.01); catalogued as COSV57338257; called by muse, mutect2, varscan2
- APC | c.6668C>A p.S2223* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as COSV57338267; called by muse, mutect2, varscan2
- APC | c.7295C>T p.S2432L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99966316; called by muse, mutect2
- API5 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 37/167 reads (22%) | catalogued as COSV66632910; called by muse, mutect2, varscan2
- APLF | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs762894469, COSV58144041; called by mutect2, varscan2
- APLP1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV55702748; called by muse, mutect2, varscan2
- APLP1 | c.1714G>T p.A572S (on ENST00000221891 / NM_001024807.3; = p.A571S on NM_005166.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.116); catalogued as COSV55702756; called by muse, mutect2, varscan2
- APMAP | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200046619; called by muse, varscan2
- APOA4 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs753407230, COSV63360319; called by mutect2, varscan2
- APOA5 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); catalogued as COSV57062961; called by muse, mutect2, varscan2
- APOB | c.11687C>T p.A3896V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as rs759708973, COSV51931713; called by muse, mutect2, varscan2
- APOB | c.10096C>A p.L3366I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV51931731; called by muse, mutect2, varscan2
- APOB | c.8920T>G p.L2974V | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV51931741; called by muse, mutect2, varscan2
- APOBEC3G | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV68470243; called by muse, mutect2, varscan2
- APOBEC3G | c.377T>G p.F126C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68470244; called by muse, mutect2, varscan2
- APOOL | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 83/642 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64271504; called by muse, mutect2, varscan2
- APP | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs760615902, COSV60997213; called by muse, mutect2, varscan2
- APTX | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs149867156, COSV100541302; called by muse, mutect2, varscan2
- ARAF | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV51692445; called by muse, mutect2
- ARAP2 | c.1042-1G>T p.X348_splice | Splice Site (SNP) | VAF 31/253 reads (12%) | catalogued as COSV58285436; called by muse, mutect2, varscan2
- ARAP2 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs752381896, COSV58284849; called by muse, mutect2, varscan2
- ARF4 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 33/352 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100327149; called by muse, mutect2
- ARFGEF1 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV51602242; called by muse, mutect2, varscan2
- ARFIP1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61884145, COSV61885304; called by muse, mutect2, varscan2
- ARG1 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV51580891; called by muse, mutect2, varscan2
- ARG2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 194/670 reads (29%) | catalogued as COSV55775800; called by muse, mutect2, varscan2
- ARGLU1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV62271331; called by muse, mutect2, varscan2
- ARHGAP11A | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV64380832; called by muse, mutect2, varscan2
- ARHGAP11A | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as rs776172390, COSV64380835; called by muse, mutect2, varscan2
- ARHGAP18 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs370593148; called by muse, mutect2, varscan2
- ARHGAP19 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.357); catalogued as rs1394594504, COSV57392289, COSV57393531; called by muse, mutect2, varscan2
- ARHGAP20 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV52809551, COSV52817335; called by muse, mutect2, varscan2
- ARHGAP21 | c.2366G>T p.R789I | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57604635; called by muse, mutect2, varscan2
- ARHGAP26 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.545); catalogued as rs374932134, COSV50827680; called by muse, mutect2, varscan2
- ARHGAP28 | c.923C>T p.S308L (on ENST00000383472 / NM_001366230.1; = p.S149L on NM_001010000.3) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV51635370, COSV99148434; called by muse, mutect2, varscan2
- ARHGAP29 | c.3178G>T p.D1060Y | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV53110564; called by muse, mutect2, varscan2
- ARHGAP29 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs41311170, COSV53110573; called by muse, mutect2, varscan2
- ARHGAP29 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs757995655, COSV53109880; called by muse, mutect2, varscan2
- ARHGAP31 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51791627; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP5 | c.2545C>A p.H849N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747803256, COSV61534989, COSV61535562; called by muse, mutect2, varscan2
- ARHGAP5 | c.4046C>A p.S1349Y (on ENST00000345122 / NM_001030055.2; = p.S1348Y on NM_001173.3) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99391925; called by muse, mutect2
- ARHGEF10 | c.2896G>A p.E966K (on ENST00000398564; = p.E941K on NM_014629.4) | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as rs1033127963, COSV50646128; called by muse, mutect2, varscan2
- ARHGEF11 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1388884489, CM142294, COSV100168393; called by muse, mutect2, varscan2
- ARHGEF12 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1436675407, COSV63103826; called by muse, mutect2, varscan2
- ARHGEF12 | c.1390T>C p.Y464H | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as COSV63103830; called by muse, mutect2, varscan2
- ARHGEF25 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54085860; called by muse, mutect2, varscan2
- ARHGEF26 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766480661, COSV62845509; called by muse, mutect2, varscan2
- ARHGEF5 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 96/520 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV50209324; called by muse, mutect2, varscan2
- ARHGEF6 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51689511; called by muse, mutect2, varscan2
- ARHGEF6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs759340844, COSV51687739; called by muse, mutect2, varscan2
- ARID1B | c.5977G>T p.A1993S | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV51657999; called by muse, mutect2, varscan2
- ARID2 | c.3877C>A p.L1293I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV57601520; called by muse, mutect2, varscan2
- ARID4B | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as rs1176638074, COSV51601640; called by muse, mutect2, varscan2
- ARL1 | c.546A>C p.*182Yext*30 | Nonstop Mutation (SNP) | VAF 38/308 reads (12%) | catalogued as COSV55370153; called by muse, mutect2, varscan2
- ARMC1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 62/222 reads (28%) | catalogued as COSV52533451; called by muse, varscan2
- ARMC3 | c.1942C>A p.H648N | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53059646; called by muse, mutect2, varscan2
- ARMC3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473023972, COSV53059669; called by muse, mutect2, varscan2
- ARMCX1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); catalogued as COSV65705044; called by muse, mutect2, varscan2
- ARMCX1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.842); catalogued as COSV65705049; called by muse, mutect2, varscan2
- ARMCX3 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV57870140, COSV57871011; called by muse, mutect2, varscan2
- ARMCX5 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405965221, COSV55766354; called by muse, mutect2, varscan2
- ARMCX6 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs1394578185, COSV62680669; called by muse, mutect2, varscan2
- ARMH4 | c.1540T>C p.S514P | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV50763312; called by muse, mutect2
- ARNTL | c.971T>C p.V324A (on ENST00000403290 / NM_001297719.2; = p.V323A on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62985427; called by muse, mutect2, varscan2
- ARPC2 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 22/164 reads (13%) | catalogued as COSV55283918; called by muse, mutect2, varscan2
- ARSJ | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59537551; called by muse, mutect2, varscan2
- ARSJ | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV59537558; called by muse, mutect2, varscan2
- ARSK | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs368614197; called by muse, mutect2, varscan2
- ASAP2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 105/351 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1209147766, COSV55628638; called by muse, mutect2, varscan2
- ASAP2 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV55627197; called by muse, mutect2, varscan2
- ASB12 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV62856562; called by muse, mutect2, varscan2
- ASB7 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV60417723; called by muse, varscan2
- ASB9 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66851586; called by muse, mutect2, varscan2
- ASH1L | c.3838C>T p.R1280* | Nonsense Mutation (SNP) | VAF 49/170 reads (29%) | catalogued as COSV64207078; called by muse, varscan2
- ASH1L | c.3677C>A p.S1226Y | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV64205610, COSV64207083; called by muse, varscan2
- ASH1L | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs867128307, COSV64205328; called by muse, mutect2, varscan2
- ASIC5 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs142024528; called by muse, mutect2, varscan2
- ASNSD1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs753403228, COSV53623167, COSV99641395; called by muse, mutect2, varscan2
- ASNSD1 | c.1826G>T p.R609I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53623474; called by muse, mutect2, varscan2
- ASPH | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 40/278 reads (14%) | catalogued as COSV65244129; called by muse, mutect2, varscan2
- ASPH | c.1293A>C p.Q431H | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65244134; called by muse, varscan2
- ASPH | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.423); catalogued as COSV62858495, COSV62858754; called by muse, mutect2, varscan2
- ASPM | c.7586G>A p.R2529K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54128248; called by muse, mutect2, varscan2
- ASPM | c.4180C>A p.L1394I | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as rs759544893, COSV54128259; called by muse, mutect2, varscan2
- ASPM | c.1949C>A p.S650Y | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54128271, COSV54128675; called by muse, mutect2
- ASPSCR1 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60728224; called by muse, mutect2, varscan2
- ASTL | c.459C>A p.C153* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV60903656, COSV60904532; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 56/198 reads (28%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ASXL3 | c.6475T>G p.F2159V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99323994; called by muse, mutect2
- ATAD2 | c.3184G>T p.E1062* | Nonsense Mutation (SNP) | VAF 11/160 reads (7%) | catalogued as COSV99784301; called by muse, mutect2
- ATAD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54879779; called by muse, mutect2, varscan2
- ATAD2B | c.4034C>A p.P1345H | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV53197271; called by muse, mutect2, varscan2
- ATAD2B | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as COSV53197278; called by muse, mutect2, varscan2
- ATF2 | c.225C>A p.F75L | Missense Mutation (SNP) | VAF 111/424 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV51368682; called by muse, mutect2, varscan2
- ATF6 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771212825, COSV63406819; called by muse, mutect2, varscan2
- ATG9A | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1349892462, COSV54694909; called by muse, mutect2, varscan2
- ATL1 | c.863-1G>T p.X288_splice | Splice Site (SNP) | VAF 20/128 reads (16%) | catalogued as COSV63296258; called by muse, mutect2, varscan2
- ATL3 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV60295353; called by muse, varscan2
- ATM | c.7310A>G p.Y2437C | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1555122944, COSV53737967, COSV53747491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10D | c.544C>A p.R182S | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV56706484; called by muse, mutect2, varscan2
- ATP10D | c.3178G>T p.D1060Y | Missense Mutation (SNP) | VAF 69/554 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56706494; called by muse, mutect2, varscan2
- ATP11B | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 58/473 reads (12%) | catalogued as COSV60027754; called by muse, mutect2, varscan2
- ATP11B | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV60027762; called by muse, mutect2, varscan2
- ATP11B | c.3148C>A p.L1050I | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60027776; called by muse, mutect2, varscan2
- ATP11C | c.2620G>T p.A874S | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.145); catalogued as COSV59562289; called by muse, mutect2, varscan2
- ATP13A3 | c.3428G>A p.R1143H | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs779940673, COSV55461560; called by muse, mutect2, varscan2
- ATP13A3 | c.3065C>A p.S1022Y | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55463498; called by muse, mutect2, varscan2
- ATP1A1 | c.1522A>C p.K508Q | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190788; called by muse, mutect2, varscan2
- ATP1B1 | c.383-1G>A p.X128_splice | Splice Site (SNP) | VAF 18/232 reads (8%) | catalogued as COSV100891613; called by muse, mutect2
- ATP1B1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs758593381, COSV63166296; called by muse, mutect2, varscan2
- ATP2A1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1217263743, COSV63920520; called by muse, mutect2, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV53806099; called by muse, mutect2, varscan2
- ATP2B1 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1314253150, COSV53806452; called by muse, mutect2, varscan2
- ATP2B1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53806470; called by muse, mutect2, varscan2
- ATP2B2 | c.2601C>A p.F867L (on ENST00000352432; = p.F833L on NM_001683.5) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59493158; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP2C2 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as rs531822897, COSV52294612, COSV52299276; called by mutect2, varscan2
- ATP5F1A | c.1639T>G p.F547V | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56360176; called by muse, mutect2, varscan2
- ATP6AP2 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101011432, COSV65797478; called by muse, mutect2, varscan2
- ATP6V0A1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1050799200, COSV52872209; called by muse, mutect2, varscan2
- ATP6V0A2 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 104/379 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57748725; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59474577; called by muse, mutect2, varscan2
- ATP6V0E1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 190/675 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54184203; called by muse, mutect2, varscan2
- ATP6V1B2 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52353280; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.021); catalogued as rs949243226, COSV52353287; called by muse, mutect2, varscan2
- ATP6V1C2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1417106963, COSV55359404; called by muse, mutect2
- ATP6V1D | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53599301; called by muse, mutect2, varscan2
- ATP6V1H | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 87/561 reads (16%) | catalogued as COSV62217867; called by muse, mutect2, varscan2
- ATP7A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV58444929; called by muse, mutect2, varscan2
- ATP7A | c.3623G>T p.R1208I | Missense Mutation (SNP) | VAF 93/774 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs146392305, COSV100430491; called by muse, mutect2, varscan2
- ATP8A1 | c.653G>T p.R218I | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV52532802; called by muse, mutect2, varscan2
- ATP8B4 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 22/256 reads (9%) | catalogued as COSV99464456; called by muse, mutect2
- ATP8B4 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 50/212 reads (24%) | catalogued as COSV52713443; called by muse, mutect2, varscan2
- ATR | c.7219C>T p.R2407C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746049210, COSV63384106; called by muse, mutect2, varscan2
- ATR | c.4102C>T p.R1368* | Nonsense Mutation (SNP) | VAF 38/270 reads (14%) | catalogued as rs1194388677, COSV63385619; called by muse, mutect2, varscan2
- ATR | c.3548G>A p.R1183Q | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as rs780802796, COSV63385620; called by muse, mutect2, varscan2
- ATRNL1 | c.3420G>A p.S1140= | Splice Region (SNP) | VAF 14/137 reads (10%) | catalogued as rs776297873, COSV58074963, COSV58099812; called by muse, mutect2, varscan2
- ATRNL1 | c.3608C>T p.T1203I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1554971632, COSV58083009; called by muse, mutect2, varscan2
- ATRX | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 48/212 reads (23%) | catalogued as COSV64874759; called by muse, mutect2, varscan2
- ATRX | c.3392G>T p.R1131I | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV64872016, COSV64874765; called by muse, mutect2, varscan2
- ATRX | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV64874772, COSV64886156; called by muse, mutect2, varscan2
- ATRX | c.2898G>T p.E966D | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs138256318, COSV64884191; called by muse, mutect2, varscan2
- ATRX | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.69); catalogued as COSV64874779; called by muse, mutect2, varscan2
- ATRX | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV64874785; called by muse, mutect2, varscan2
- AVIL | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs549145073, COSV57680547; called by muse, mutect2, varscan2
- AWAT2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as COSV52142874; called by muse, mutect2
- AXDND1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766225252, COSV62639335; called by muse, mutect2
- B3GNT5 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.123); catalogued as COSV58475785; called by muse, mutect2, varscan2
- B4GALT3 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs745448974, COSV60526936; called by muse, mutect2, varscan2
- B4GALT7 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs1416146236, COSV50353061; called by muse, mutect2, varscan2
- BAAT | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); catalogued as COSV52288144; called by muse, mutect2, varscan2
- BAAT | c.672C>A p.V224= | Splice Region (SNP) | VAF 11/93 reads (12%) | catalogued as COSV52288153; called by muse, mutect2, varscan2
- BAAT | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV52287479; called by muse, mutect2, varscan2
- BAG6 | c.2816G>A p.R939Q (on ENST00000676571; = p.R892Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs904232684; called by mutect2, varscan2
- BAIAP3 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100181203; called by muse, mutect2
- BAK1 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100645834; called by muse, mutect2
- BANK1 | c.1010-1G>T p.X337_splice | Splice Site (SNP) | VAF 11/97 reads (11%) | catalogued as COSV59841490; called by muse, mutect2
- BARX2 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99858461; called by muse, mutect2
- BATF3 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54658038; called by muse, mutect2, varscan2
- BAZ1B | c.3427G>T p.A1143S | Missense Mutation (SNP) | VAF 54/503 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV59990352; called by muse, varscan2
- BAZ1B | c.3419T>C p.V1140A | Missense Mutation (SNP) | VAF 172/552 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1264661003, COSV59990365; called by muse, varscan2
- BAZ1B | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 34/309 reads (11%) | catalogued as COSV59990372; called by muse, mutect2, varscan2
- BAZ1B | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs999125819, COSV59990381; called by muse, mutect2, varscan2
- BAZ2B | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755763510, COSV54275303; called by muse, mutect2, varscan2
- BAZ2B | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 122/443 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV58598699; called by muse, mutect2, varscan2
- BBS10 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV53881041; called by muse, mutect2, varscan2
- BBS9 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54163967; called by muse, mutect2, varscan2
- BBS9 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 30/308 reads (10%) | catalogued as COSV99626966; called by muse, mutect2, varscan2
- BCAS2 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 104/371 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65767391; called by muse, mutect2, varscan2
- BCAS3 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV66405047; called by muse, mutect2, varscan2
- BCAS3 | c.2434C>T p.R812* (on ENST00000390652 / NM_001353144.2; = p.R797* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV66772462; called by muse, mutect2, varscan2
- BCKDHB | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 79/579 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57511752; called by muse, mutect2, varscan2
- BCL10 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV65353721; called by muse, mutect2, varscan2
- BCL11B | c.2500G>A p.A834T (on ENST00000357195 / NM_001282237.2; = p.A763T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1398057798, COSV61735370; called by muse, mutect2
- BCL2L1 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100304626; called by muse, mutect2
- BCLAF3 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 93/413 reads (23%) | catalogued as COSV61413630; called by muse, mutect2, varscan2
- BCLAF3 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 121/394 reads (31%) | catalogued as COSV61413177; called by muse, mutect2, varscan2
- BCO1 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV99257606; called by muse, mutect2
- BCO2 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489775673, COSV63063050; called by muse, mutect2, varscan2
- BCO2 | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs781512153, COSV63063058; called by muse, mutect2, varscan2
- BCOR | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs775994643, COSV60705111; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BDKRB2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.027); catalogued as rs776833029, COSV60013703; called by muse, mutect2
- BDKRB2 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1239271323, COSV60013532; called by muse, mutect2, varscan2
- BEND2 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66215585; called by muse, varscan2
- BEND5 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs776938575, COSV65717014; called by muse, mutect2, varscan2
- BIRC2 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as rs779636887, COSV57160738, COSV57161083; called by muse, mutect2, varscan2
- BIRC2 | c.1356A>C p.E452D | Missense Mutation (SNP) | VAF 120/487 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV57161093; called by muse, mutect2, varscan2
- BIRC6 | c.6674G>T p.R2225I | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70198008; called by muse, mutect2, varscan2
- BIRC6 | c.14174G>A p.R4725Q | Missense Mutation (SNP) | VAF 69/479 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as COSV70198010; called by muse, mutect2, varscan2
- BLNK | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV56410245; called by muse, mutect2, varscan2
- BLOC1S6 | c.519A>G p.*173Wext*21 | Nonstop Mutation (SNP) | VAF 72/778 reads (9%) | catalogued as COSV99593333; called by muse, mutect2
- BLVRA | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55513749; called by muse, mutect2, varscan2
- BMI1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV64958923; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BMP5 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 47/437 reads (11%) | catalogued as COSV63701851, COSV63702549; called by muse, mutect2, varscan2
- BMPR1B | c.1467A>C p.K489N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52776400; called by muse, varscan2
- BMPR2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs777889469, COSV65808703; called by muse, mutect2, varscan2
- BMX | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as COSV100564374; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, mutect2, varscan2
- BNC2 | c.3265C>T p.L1089F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101035612; called by muse, mutect2
- BNIP5 | c.1886A>G p.Y629C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV71325488; called by muse, mutect2, varscan2
- BOC | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56349491; called by muse, mutect2, varscan2
- BOD1L1 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 22/165 reads (13%) | catalogued as COSV50009652, COSV99238984; called by muse, mutect2, varscan2
- BOD1L1 | c.2413G>T p.D805Y | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99238838; called by muse, mutect2
- BOLL | c.18A>C p.L6F | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV56573968; called by muse, mutect2, varscan2
- BORA | c.457C>T p.R153C (on ENST00000613797; = p.R78C on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1351632765, COSV64695124; called by muse, mutect2, varscan2
- BORA | c.1636G>T p.E546* (on ENST00000613797; = p.E471* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 71/307 reads (23%) | catalogued as COSV64695127; called by muse, mutect2, varscan2
- BPHL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 110/202 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs774197466, COSV66743046; called by muse, mutect2, varscan2
- BPIFA3 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | catalogued as COSV64925757; called by muse, mutect2, varscan2
- BPIFB6 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs779003259, COSV62754699; called by muse, mutect2, varscan2
- BPIFC | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV53277480; called by muse, mutect2, varscan2
- BRAP | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1487158294, COSV59536219; called by muse, mutect2, varscan2
- BRAP | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.195); catalogued as COSV59536231; called by muse, varscan2
- BRCA1 | c.3292C>A p.L1098I | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as COSV58784240; called by muse, mutect2, varscan2
- BRCA2 | c.2954A>T p.K985I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as CD161654, COSV101204034; called by muse, mutect2
- BRCA2 | c.10024G>A p.E3342K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs28897761, COSV66337145; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- BRD8 | c.2053G>A p.D685N (on ENST00000254900 / NM_139199.2; = p.D758N on NM_006696.4) | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50146754; called by muse, mutect2, varscan2
- BRINP3 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs146936488; called by mutect2, varscan2
- BRINP3 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV66518014, COSV66518629; called by muse, mutect2, varscan2
- BRIP1 | c.2800T>G p.F934V | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs863224801, COSV51997754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRMS1L | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 146/542 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53762926; called by muse, mutect2, varscan2
- BRSK1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58664546, COSV58665929; called by muse, mutect2
- BRWD1 | c.2423G>T p.R808I | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV60894635; called by muse, mutect2, varscan2
- BRWD3 | c.5359A>G p.K1787E | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV64746757; called by muse, mutect2, varscan2
- BRWD3 | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | catalogued as COSV64746439; called by muse, varscan2
- BRWD3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1236574829, COSV64745626; called by muse, mutect2, varscan2
- BSN | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs968160275, COSV56516056; called by muse, varscan2
- BTBD1 | c.711A>C p.E237D | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55602576; called by muse, mutect2, varscan2
- BTBD10 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs1445744205, COSV53398674; called by muse, varscan2
- BTBD16 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs764340155, COSV53262181; called by muse, mutect2, varscan2
- BTNL3 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61564770; called by muse, varscan2
- BTNL3 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 152/442 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV61564772; called by muse, mutect2, varscan2
- BTNL8 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 71/660 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51458108; called by muse, mutect2, varscan2
- BVES | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV58947325; called by muse, mutect2, varscan2
- C10orf71 | c.1277C>A p.A426D | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV60504079; called by muse, mutect2
- C10orf71 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV60506677; called by muse, mutect2, varscan2
- C10orf82 | c.167T>G p.L56W | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV65024535; called by muse, mutect2, varscan2
- C10orf90 | c.1026T>G p.S342R | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV52953215; called by muse, mutect2, varscan2
- C12orf40 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745941127, COSV61131230; called by muse, mutect2, varscan2
- C12orf71 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374505766, COSV70282633; called by muse, mutect2, varscan2
- C14orf39 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs758761993, COSV58781130; called by muse, mutect2, varscan2
- C14orf39 | c.1248G>T p.E416D | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58781142; called by muse, mutect2, varscan2
- C14orf39 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1219258922, COSV58781162; called by muse, mutect2, varscan2
- C14orf93 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs17851131, COSV54440759; called by muse, mutect2, varscan2
- C19orf18 | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV58705649; called by muse, mutect2, varscan2
- C1GALT1 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56179184; called by muse, mutect2, varscan2
- C1GALT1C1 | c.162A>C p.K54N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV58973983; called by muse, mutect2, varscan2
- C1QTNF3 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.134); catalogued as rs551906960, COSV51468315; called by muse, mutect2, varscan2
- C1QTNF9 | c.282A>C p.R94S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); catalogued as rs1444932881, COSV59656900; called by muse, mutect2, varscan2
- C1QTNF9 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 54/165 reads (33%) | catalogued as rs777575333, COSV59656910; called by muse, mutect2, varscan2
- C1RL | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99864518; called by muse, mutect2
- C1orf141 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as rs548899130, COSV63992480; called by muse, mutect2, varscan2
- C1orf141 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs147612243; called by muse, mutect2, varscan2
- C1orf43 | c.193C>T p.R65* (on ENST00000368521 / NM_001297718.2; = p.R31* on NM_015449.4) | Nonsense Mutation (SNP) | VAF 32/138 reads (23%) | catalogued as rs766685758, COSV62966119; called by muse, mutect2, varscan2
- C20orf96 | c.1021C>T p.R341W (on ENST00000360321 / NM_153269.3; = p.R340W on NM_080571.1) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1246943904, COSV64403404; called by muse, mutect2, varscan2
- C21orf62 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV66671872; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2CD6 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs779021017, COSV53791293; called by muse, mutect2, varscan2
- C2orf16 | c.4330G>T p.A1444S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV62674959; called by muse, mutect2, varscan2
- C2orf16 | c.4723C>T p.R1575C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs780592631, COSV62674964; called by muse, varscan2
- C2orf78 | c.1950C>A p.F650L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753364861, COSV68516704, COSV68519366; called by muse, mutect2, varscan2
- C3 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV55571503; called by muse, mutect2, varscan2
- C3orf18 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144985331; called by mutect2, varscan2
- C3orf38 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as rs1348452549, COSV59627599; called by muse, mutect2, varscan2
- C4BPA | c.1325C>A p.S442* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as COSV65536194; called by muse, mutect2, varscan2
- C5 | c.4517C>T p.T1506I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56327870; called by muse, mutect2
- C5 | c.711C>A p.F237L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV99797435; called by muse, mutect2, varscan2
- C5AR1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs763510565, COSV61892435; called by mutect2, varscan2
- C5orf51 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV67565723; called by muse, mutect2, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, mutect2, varscan2
- C6orf58 | c.153T>G p.I51M | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61666327; called by muse, mutect2, varscan2
- C6orf58 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61666334; called by muse, mutect2, varscan2
- C7orf31 | c.608G>T p.R203I | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52216893; called by muse, mutect2, varscan2
- C7orf57 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 29/262 reads (11%) | catalogued as COSV62362409; called by muse, mutect2, varscan2
- C8A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as rs749738757, COSV63483668; called by muse, mutect2
- C8A | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63483672; called by muse, mutect2, varscan2
- C9 | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 60/587 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54676049, COSV54680943; called by muse, mutect2, varscan2
- C9orf24 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV52624227; called by muse, mutect2, varscan2
- C9orf43 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 57/489 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV55912439; called by muse, mutect2, varscan2
- C9orf78 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV61028908; called by muse, mutect2
- CABLES1 | c.923G>A p.R308Q (on ENST00000256925 / NM_001100619.2; = p.R43Q on NM_138375.2) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1230797331, COSV56930953; called by muse, mutect2, varscan2
- CACHD1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 23/127 reads (18%) | catalogued as COSV51551815; called by muse, mutect2, varscan2
- CACNA1C | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59709919; called by muse, mutect2, varscan2
- CACNA1D | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV55455212, COSV99857219; called by muse, mutect2
- CACNA1D | c.1705G>A p.E569K (on ENST00000350061 / NM_001128840.3; = p.E589K on NM_000720.4) | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55443946; called by muse, mutect2, varscan2
- CACNA1S | c.4999A>G p.N1667D | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.265); catalogued as COSV62938659; called by muse, mutect2
- CACNA2D1 | c.2687A>T p.K896I (on ENST00000356253 / NM_001366867.1; = p.K884I on NM_000722.4) | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV62377282; called by muse, mutect2, varscan2
- CACNA2D1 | c.2108A>G p.N703S (on ENST00000356253 / NM_001366867.1; = p.N691S on NM_000722.4) | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62377288; called by muse, mutect2, varscan2
- CACNA2D1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62377292; called by muse, mutect2, varscan2
- CACNA2D1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as rs373911809; called by muse, mutect2, varscan2
- CACNB2 | c.427G>A p.E143K (on ENST00000324631 / NM_201596.3; = p.E88K on NM_000724.4) | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs368719191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV50066181, COSV50082101; called by muse, mutect2, varscan2
- CAD | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1377680993, COSV99254680; called by muse, mutect2
- CADPS | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as rs772497329, COSV51869359; called by muse, mutect2, varscan2
- CADPS2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1457955627, COSV57358802; called by muse, mutect2, varscan2
- CAGE1 | c.2318G>T p.R773I (on ENST00000512086; = p.R637I on NM_205864.3) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as COSV57076477; called by muse, mutect2, varscan2
- CAGE1 | c.2218A>G p.I740V (on ENST00000512086; = p.I604V on NM_205864.3) | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV57076503; called by muse, mutect2, varscan2
- CALCR | c.1327C>T p.R443C (on ENST00000649521 / NM_001164737.2; = p.R427C on NM_001742.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV64007358; called by muse, mutect2, varscan2
- CALD1 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 417/3094 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV62645441; called by muse, varscan2
- CAMK2B | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51659304; called by muse, varscan2
- CAMSAP1 | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764759860, COSV56721299; called by muse, varscan2
- CAMSAP1 | c.4647G>T p.K1549N | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56718323; called by muse, varscan2
- CAMSAP2 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV52669347; called by muse, mutect2, varscan2
- CAMSAP3 | c.3365A>C p.K1122T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50332648; called by muse, mutect2, varscan2
- CAMTA1 | c.148A>C p.K50Q | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57894563; called by muse, mutect2, varscan2
- CAND1 | c.3425T>C p.L1142S | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV73389582; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN6 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as rs141738051, COSV60694301, COSV60697049; called by muse, mutect2, varscan2
- CAPS2 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 32/224 reads (14%) | catalogued as rs201652520; called by muse, varscan2
- CAPS2 | c.1095T>G p.F365L | Missense Mutation (SNP) | VAF 125/466 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV60824888; called by muse, varscan2
- CAPZA2 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 30/234 reads (13%) | catalogued as COSV63266325; called by muse, mutect2, varscan2
- CAPZA3 | c.165C>A p.H55Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV56852525, COSV99856060; called by muse, mutect2
- CARD6 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54565625; called by muse, mutect2
- CARD6 | c.1853G>T p.R618I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV54565643; called by muse, mutect2, varscan2
- CARMIL3 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV57725904; called by muse, mutect2, varscan2
- CASD1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51971870, COSV99802796; called by muse, mutect2, varscan2
- CASP1 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 34/244 reads (14%) | catalogued as COSV62056303, COSV62057626; called by muse, varscan2
- CASP14 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 125/442 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55664793; called by muse, mutect2, varscan2
- CASP3 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 57/214 reads (27%) | catalogued as rs1037653105, COSV57724864; called by muse, mutect2, varscan2
- CASP5 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 74/491 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV52827982; called by muse, mutect2, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by muse, mutect2, varscan2
- CASQ2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as COSV54769814; called by muse, mutect2, varscan2
- CASS4 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767728589, COSV64386016; called by muse, mutect2, varscan2
- CASZ1 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59734446, COSV59735832; called by muse, mutect2, varscan2
- CATSPER3 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99253984; called by muse, mutect2
- CATSPER4 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV58792776, COSV58792833; called by muse, mutect2, varscan2
- CATSPERB | c.2219A>C p.N740T | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV56425055; called by muse, mutect2, varscan2
- CATSPERE | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as COSV63677280; called by muse, mutect2, varscan2
- CATSPERE | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1228636188, COSV63677287; called by muse, mutect2, varscan2
- CATSPERE | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV63677295; called by muse, mutect2, varscan2
- CAVIN2 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414323, COSV58423821; called by muse, mutect2, varscan2
- CAVIN2 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV58423827; called by muse, mutect2
- CBFA2T2 | c.1774A>G p.T592A | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV60798276; called by muse, mutect2, varscan2
- CBL | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as rs759585425, COSV50639868; called by muse, mutect2
- CBLB | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as rs748390313, COSV51424925; called by muse, mutect2, varscan2
- CBLB | c.68T>G p.L23W | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51424966; called by muse, mutect2, varscan2
- CBLC | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54322092; called by muse, mutect2, varscan2
- CBLIF | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 99/299 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57238593; called by muse, mutect2, varscan2
- CBX8 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.675); catalogued as COSV53936183; called by muse, mutect2, varscan2
- CC2D2A | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as rs749997192, COSV67502420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CC2D2B | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 32/256 reads (13%) | catalogued as COSV60357666; called by muse, varscan2
- CCAR1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as COSV56269013; called by muse, varscan2
- CCAR1 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1221967997, COSV56269025, COSV99770445; called by muse, varscan2
- CCDC102A | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs758173864, COSV50776121; called by muse, mutect2, varscan2
- CCDC110 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as rs1176222863, COSV56870390; called by muse, varscan2
- CCDC112 | c.1331G>T p.R444I | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65472981; called by muse, mutect2, varscan2
- CCDC114 | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs1249278523, COSV59556179; called by muse, mutect2
- CCDC12 | c.389G>T p.R130L (on ENST00000425441 / NM_001277074.1; = p.R143L on NM_144716.5) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99438760; called by mutect2, varscan2
- CCDC121 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV53114050; called by muse, mutect2, varscan2
- CCDC122 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV55708664, COSV99865881; called by muse, mutect2, varscan2
- CCDC138 | c.1178G>T p.R393I | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV54566192; called by muse, mutect2, varscan2
- CCDC144A | c.2479G>T p.E827* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV60697715; called by muse, mutect2, varscan2
- CCDC146 | c.2558C>A p.S853Y | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.627); catalogued as COSV53546937, COSV53553542; called by muse, mutect2, varscan2
- CCDC148 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 19/166 reads (11%) | catalogued as rs752963296, COSV51757126; called by muse, mutect2, varscan2
- CCDC150 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV55873628; called by muse, mutect2, varscan2
- CCDC150 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs907987145, COSV55873637, COSV55878786, COSV99776557; called by muse, mutect2, varscan2
- CCDC158 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as rs539971875, COSV66355611; called by muse, mutect2, varscan2
- CCDC160 | c.181T>A p.F61I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV66251497; called by muse, mutect2
- CCDC171 | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs766978058, COSV52639596; called by muse, mutect2, varscan2
- CCDC173 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 159/596 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71428580; called by muse, mutect2, varscan2
- CCDC174 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 43/151 reads (28%) | catalogued as COSV57980621, COSV99070631; called by muse, mutect2, varscan2
- CCDC18 | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | catalogued as COSV58142612; called by muse, mutect2, varscan2
- CCDC181 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 84/332 reads (25%) | catalogued as COSV63155612; called by muse, varscan2
- CCDC181 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs530288123, COSV63155897; called by muse, varscan2
- CCDC186 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs758664195, COSV65161010; called by muse, mutect2, varscan2
- CCDC186 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 110/1564 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757447418, COSV65161999; called by muse, mutect2
- CCDC186 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 70/565 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV65161016; called by muse, mutect2, varscan2
- CCDC3 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66559336; called by muse, mutect2, varscan2
- CCDC34 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 200/801 reads (25%) | catalogued as COSV58725581; called by muse, mutect2, varscan2
- CCDC38 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV60182804; called by muse, mutect2, varscan2
- CCDC38 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100717456; called by muse, mutect2
- CCDC40 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); catalogued as rs775425348, COSV66474090; called by muse, mutect2, varscan2
- CCDC50 | c.1084G>T p.E362* (on ENST00000392455 / NM_178335.3; = p.E186* on NM_174908.4) | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | catalogued as COSV66667697; called by muse, mutect2, varscan2
- CCDC57 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs531085389, COSV58934529; called by muse, mutect2, varscan2
- CCDC62 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53432234; called by muse, mutect2
- CCDC77 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV53472282, COSV53472571; called by muse, mutect2, varscan2
- CCDC80 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1187874088, COSV52815168, COSV99245236; called by muse, mutect2, varscan2
- CCDC81 | c.1165C>A p.L389I (on ENST00000445632 / NM_001156474.2; = p.L299I on NM_021827.4) | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV53577746; called by muse, mutect2, varscan2
- CCDC83 | c.59T>G p.I20S | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54701232; called by muse, mutect2, varscan2
- CCDC83 | c.1080+2T>C p.X360_splice (on ENST00000342404 / NM_001286159.2; = p.X391_splice on NM_173556.5) | Splice Site (SNP) | VAF 12/82 reads (15%) | catalogued as rs1237867218, COSV54701241; called by muse, varscan2
- CCDC88A | c.5259T>G p.F1753L (on ENST00000436346 / NM_001365480.1; = p.F1725L on NM_018084.5) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55060010; called by muse, mutect2, varscan2
- CCDC88A | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55060025; called by muse, mutect2, varscan2
- CCDC88A | c.382T>G p.L128V | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.124); catalogued as COSV55060041; called by muse, varscan2
- CCDC88A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 36/292 reads (12%) | catalogued as COSV55060055; called by muse, varscan2
- CCDC88C | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs753170514, COSV66237111; called by muse, mutect2, varscan2
- CCDC90B | c.582A>T p.E194D | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV52623774; called by muse, mutect2, varscan2
- CCDC93 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 51/405 reads (13%) | catalogued as COSV60120818; called by muse, mutect2, varscan2
- CCKAR | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs756780999, COSV55160991; called by muse, mutect2, varscan2
- CCL19 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61337401; called by muse, mutect2, varscan2
- CCL27 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.969); catalogued as COSV99426452; called by mutect2, varscan2
- CCNA2 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.18); catalogued as COSV52655674; called by muse, mutect2, varscan2
- CCNB1IP1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.569); catalogued as COSV62302563; called by muse, mutect2, varscan2
- CCNB3 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52072336, COSV99329441; called by muse, mutect2, varscan2
- CCNB3 | c.1856A>C p.K619T | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV52072345; called by muse, mutect2, varscan2
- CCNK | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV66274584; called by muse, mutect2, varscan2
- CCPG1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1485834962, COSV51241189; called by muse, mutect2, varscan2
- CCR2 | c.34A>C p.N12H | Missense Mutation (SNP) | VAF 73/498 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV52748299; called by muse, mutect2, varscan2
- CCR2 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.06); catalogued as rs1166098549, COSV52748313; called by muse, mutect2, varscan2
- CCSER2 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56507542, COSV99825665; called by mutect2, varscan2
- CCSER2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs750250954, COSV56504046; called by muse, mutect2, varscan2
- CCT4 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV66701338; called by muse, mutect2, varscan2
- CCT8L2 | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63462153, COSV63462489, COSV63462823; called by muse, mutect2, varscan2
- CCZ1B | c.523-1G>T p.X175_splice | Splice Site (SNP) | VAF 18/127 reads (14%) | catalogued as COSV57436881; called by muse, mutect2, varscan2
- CCZ1B | c.166A>C p.N56H | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57436891; called by muse, mutect2, varscan2
- CD109 | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 33/252 reads (13%) | catalogued as COSV54648184; called by muse, mutect2, varscan2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2, varscan2
- CD163L1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58023548; called by muse, mutect2, varscan2
- CD180 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs550559471, COSV56517593; called by muse, mutect2, varscan2
- CD19 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1241372922, COSV61188315; called by muse, mutect2, varscan2
- CD1A | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 38/555 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV99192252; called by muse, mutect2
- CD1D | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs920079330, COSV63808455, COSV63808828; called by muse, mutect2
- CD1E | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs745332808, COSV63770707; called by muse, mutect2, varscan2
- CD200R1 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 266/975 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV55600116; called by muse, mutect2, varscan2
- CD22 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50051384; called by muse, mutect2
- CD274 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as COSV67501181; called by muse, mutect2, varscan2
- CD2AP | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs147188917; called by muse, mutect2
- CD300LF | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 48/409 reads (12%) | catalogued as COSV56896607; called by muse, mutect2, varscan2
- CD34 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 20/190 reads (11%) | catalogued as COSV100178257; called by muse, mutect2, varscan2
- CD38 | c.475T>G p.W159G | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56889711; called by muse, mutect2, varscan2
- CD48 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV63566386; called by muse, mutect2, varscan2
- CD55 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV58576773; called by muse, mutect2, varscan2
- CD58 | c.753A>G p.*251Wext*15 | Nonstop Mutation (SNP) | VAF 88/338 reads (26%) | catalogued as COSV65666072; called by muse, mutect2, varscan2
- CD59 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs754311428, COSV60919207; called by muse, mutect2, varscan2
- CD63 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.393); catalogued as COSV57676259; called by muse, mutect2, varscan2
- CD79A | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99701954; called by muse, mutect2
- CD84 | c.752G>T p.R251I | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs753673028, COSV100245912, COSV60867715; called by muse, mutect2, varscan2
- CDC16 | c.1828A>C p.M610L | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV52959150; called by muse, mutect2, varscan2
- CDC25A | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs3731499; called by muse, mutect2, varscan2
- CDC27 | c.2206G>T p.E736* | Nonsense Mutation (SNP) | VAF 26/161 reads (16%) | catalogued as COSV50364251; called by muse, mutect2, varscan2
- CDC27 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745491637, COSV50374936; called by muse, mutect2, varscan2
- CDC42BPA | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.107); catalogued as rs772380478, COSV62009001; called by muse, mutect2, varscan2
- CDC42BPB | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs367927706; called by mutect2, varscan2
- CDC42EP3 | c.494T>A p.V165D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV54873982; called by muse, mutect2, varscan2
- CDC5L | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 41/282 reads (15%) | catalogued as COSV65175807; called by muse, mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 255/641 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, varscan2
- CDC73 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV66465084; called by muse, mutect2, varscan2
- CDCA2 | c.821-2A>G p.X274_splice | Splice Site (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100398789; called by muse, varscan2
- CDH11 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.101); catalogued as COSV51752817; called by muse, mutect2, varscan2
- CDH16 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs1165275272, COSV55335574, COSV55340120; called by muse, mutect2, varscan2
- CDH19 | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV50956951; called by muse, varscan2
- CDH20 | c.1309T>G p.F437V | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV53008088; called by muse, mutect2, varscan2
- CDH23 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.918); catalogued as COSV54930636; called by muse, mutect2, varscan2
- CDH26 | c.232C>T p.L78= | Splice Region (SNP) | VAF 31/212 reads (15%) | catalogued as rs773652326, COSV54845578; called by muse, varscan2
- CDH7 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761037837, COSV59884438; called by muse, mutect2, varscan2
- CDH7 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.357); catalogued as rs767686297, COSV59883221; called by muse, mutect2, varscan2
- CDH7 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100541788; called by muse, mutect2
- CDH8 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV54848976, COSV54860835; called by muse, mutect2, varscan2
- CDH9 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1161575895, COSV50265477; called by muse, mutect2, varscan2
- CDHR2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as rs1395522059, COSV56136148; called by muse, mutect2
- CDK1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV57349413; called by muse, varscan2
- CDK12 | c.2776C>A p.L926I | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71000187; called by muse, mutect2, varscan2
- CDK14 | c.825C>T p.F275= (on ENST00000380050 / NM_001287135.2; = p.F257= on NM_012395.3) | Splice Region (SNP) | VAF 35/204 reads (17%) | catalogued as rs202149959, COSV56026334; called by muse, mutect2, varscan2
- CDK5 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV99876518; called by muse, mutect2
- CDK5RAP1 | c.1291G>T p.E431* (on ENST00000357886 / NM_001365728.1; = p.E417* on NM_016082.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/229 reads (26%) | catalogued as COSV59426587; called by muse, mutect2, varscan2
- CDKL1 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1275414317, COSV53578988; called by muse, mutect2, varscan2
- CDKL5 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66110862; called by muse, mutect2, varscan2
- CECR2 | c.2416T>G p.L806V (on ENST00000342247 / NM_001290047.2; = p.L623V on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.048); catalogued as COSV52839506; called by muse, mutect2, varscan2
- CECR2 | c.3656G>A p.R1219Q (on ENST00000342247 / NM_001290047.2; = p.R1035Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as rs1375445153, COSV52839531; called by muse, mutect2, varscan2
- CECR2 | c.3833C>A p.S1278Y (on ENST00000342247 / NM_001290047.2; = p.S1094Y on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV52839550, COSV52847285; called by muse, mutect2, varscan2
- CECR2 | c.4292G>T p.R1431I (on ENST00000342247 / NM_001290047.2; = p.R1247I on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52839570; called by muse, mutect2, varscan2
- CELF5 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.014); catalogued as rs777120251, COSV99485796; called by mutect2, varscan2
- CELSR3 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV50848219; called by muse, mutect2, varscan2
- CEMIP2 | c.3357C>A p.F1119L | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV65484462, COSV65484820; called by muse, mutect2, varscan2
- CENPC | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs267600207, COSV56622385; called by muse, mutect2, varscan2
- CENPC | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99893704; called by muse, mutect2, varscan2
- CENPE | c.3140C>A p.S1047Y | Missense Mutation (SNP) | VAF 55/460 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54379591; called by muse, mutect2, varscan2
- CENPE | c.1527T>G p.N509K | Missense Mutation (SNP) | VAF 75/367 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV54379602; called by muse, mutect2, varscan2
5,228 further variants in this file (4,063 protein-altering or splice-affecting, 1,059 silent, 106 other) are not listed here.
